Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6N0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6N0-01A (Primary Tumor).

Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex:
Location/Client:

Account #:
(Age: F

Surgical Pathology Report

Final Diagnosis

LEFT ADRENAL GLAND, ADRENALECTOMY:

- PHEOCHROMOCYTOMA.

A. Size of tumor: 2.3x1.8x1.5 cm

B. Extent of tumor: Tumor is confined to the adrenal gland.

C. Margins of Resection: Margins are free of tumor.

- ADRENAL CORTEX WITH NO SPECIFIC PATHOLOGIC CHANGE.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Clinical History

Left adrenal mass

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

Gross Description

A. ADRENAL GLAND, RESECTION, LEFT (FRESH): The specimen, labeled with the patient's name and accession number, is a left adrenalectomy specimen (9.5 x 4.2 x 2.1 cm) completely surrounded by yellow-white unremarkable adipose tissue, which ranges in thickness from 0.5 to 2 cm. There is a 2.5 x 1.8 x 1.5 cm round well circumscribed tan-brown and hemorrhagic mass that appears to be arising in the nodule of the adrenal gland. The mass appears to compress the adjacent cortex which is homogenous and atrophic in appearance and measures 0.2 cm in thickness. Representative sections are submitted as follows:

SECTION CODE

A1-2: SOFT TISSUE AND ADIPOSE TISSUE AWAY FROM THE MASS.
A3-8: 90% OF MASS SUBMITTED.
A7: SOFT TISSUE AFTER THE MASS.

Department of Pathology

Page 1 of 1

Printed:

Source: NCI Genomic Data Commons file d4632555-27f3-49ae-8706-0e7592a4a333 (TCGA-SR-A6N0.E61BBC2F-4FD2-45E6-8517-6B49019A8F58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).